Gene-level copy-number profile of tumor specimen HCM-BROD-0871-C49-06B from HCMI case HCM-BROD-0871-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.7 years (22,167 days).
Specimen HCM-BROD-0871-C49-06B: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56ce9fc0-b9c0-4633-9587-54a20d53ba3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0871-C49-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/318452ec-fc1f-4a4c-b513-85a3a33331b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 12,854; copy number 2: 42,234; copy number 3: 1,510; copy number 4: 902; copy number 5: 806; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,708,125–29,763,392, 12 genes: ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3.
- chr13:49,444,374–50,125,720, 25 genes (within-gene range 0–1): SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,173,181, 5 genes (within-gene range 0–1): AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4.
- chr14:18,555,677–18,667,370, 14 genes: CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 807 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,269,604–155,750,137, 496 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:168,576,605–171,824,959, 77 genes, copy number 5 (broad region; genes not listed).
- chr1:173,351,689–178,921,841, 90 genes, copy number 5 (broad region; genes not listed).
- chr1:179,082,070–180,951,614, 45 genes, copy number 5–6 (within-gene range 4–6): TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614.
- chr1:205,302,063–205,775,482, 19 genes, copy number 5: NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29.
- chr1:216,194,051–216,204,366, 2 genes, copy number 5 (within-gene range 1–5): USH2A-AS1, MRPS18BP1.
- chr1:226,870,184–228,626,027, 77 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:710,355–784,729, 1 gene, copy number 5 (within-gene range 4–5): ZDHHC11B.

Autosomal genes at a single copy (total copy number 1): 10,510. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
